Somatic mutation profile of tumor specimen TCGA-HV-A5A6-01A (aliquot TCGA-HV-A5A6-01A-11D-A26I-08) from TCGA case TCGA-HV-A5A6, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 65.8 years (24,025 days).
Specimen TCGA-HV-A5A6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 473d1878-607d-4b4a-88c8-b3551b24196a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HV-A5A6-10A (Blood Derived Normal), aliquot TCGA-HV-A5A6-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59fc3724-01a0-4d19-90ea-d6b6944e5ae5

The open-access MAF lists 49 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 38/101 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024del p.R342Efs*3 | Frame Shift Del (DEL) | VAF 53/122 reads (43%) | catalogued as rs1131691022, CM004908, COSV52665487; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AHNAK | c.2876A>C p.K959T | Missense Mutation (SNP) | VAF 28/1119 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV99947652; called by muse, mutect2
- ARHGAP6 | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 89/538 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs376590462, COSV100272625, COSV100273532; called by muse, mutect2, varscan2
- BCR | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 86/297 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.488); catalogued as rs1302621798, COSV100006683; called by muse, mutect2, varscan2
- CAD | c.2156+1G>A p.X719_splice | Splice Site (SNP) | VAF 56/180 reads (31%) | catalogued as COSV99255625; called by muse, mutect2, varscan2
- CAPZA1 | c.18T>A p.D6E | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.663); catalogued as COSV99583439; called by muse, mutect2
- CAPZA1 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs914151348, COSV54144351; called by muse, mutect2
- CEPT1 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 152/548 reads (28%) | catalogued as COSV64111231; called by muse, mutect2, varscan2
- CHST12 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 105/584 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs1486326455, COSV99324664; called by muse, mutect2, varscan2
- ECT2 | c.2537C>T p.T846I (on ENST00000392692 / NM_001349098.2; = p.T815I on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99221846; called by muse, mutect2, varscan2
- EXOC5 | c.955A>T p.S319C | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV100567252; called by muse, mutect2, varscan2
- FAM214A | c.223A>G p.R75G | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99958473; called by muse, mutect2, varscan2
- GCFC2 | c.1644dup p.V549Sfs*42 | Frame Shift Ins (INS) | VAF 67/487 reads (14%) | catalogued as rs757231207; called by mutect2, pindel, varscan2
- GRK2 | c.555C>T p.H185= | Splice Region (SNP) | VAF 351/1129 reads (31%) | catalogued as rs747352703, COSV100419738; called by muse, mutect2, varscan2
- IFT81 | c.1943G>A p.C648Y | Missense Mutation (SNP) | VAF 168/591 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs150790899, COSV99656352; called by muse, mutect2, varscan2
- IL34 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 46/449 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs749803529, COSV55382121; called by muse, mutect2, varscan2
- KIF4B | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 176/364 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753391654, COSV70529106; called by muse, mutect2, varscan2
- LUZP1 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 123/415 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as COSV100035410; called by muse, mutect2, varscan2
- MEFV | c.2093A>G p.E698G | Missense Mutation (SNP) | VAF 210/663 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV99561229; called by muse, mutect2, varscan2
- MOV10L1 | c.2875G>A p.A959T | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs372963947; called by muse, mutect2, varscan2
- OR2A14 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 150/607 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV101376489, COSV68718110; called by muse, mutect2, varscan2
- OR8U1 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 157/526 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs764656297, COSV56414529; called by muse, mutect2, varscan2
- PCSK2 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 79/288 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs144151196; called by muse, mutect2, varscan2
- PIWIL1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144603967, COSV55345055; called by muse, mutect2, varscan2
- PLPPR4 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 177/542 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV100926912; called by muse, mutect2, varscan2
- SF1 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.028); catalogued as rs765841152, COSV57112232, COSV99918742; called by muse, mutect2, varscan2
- SLC6A2 | c.1551G>T p.W517C | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99574515; called by muse, mutect2, varscan2
- SLC7A3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as rs748007422, COSV99979830; called by muse, mutect2, varscan2
- SPEN | c.9283C>T p.Q3095* | Nonsense Mutation (SNP) | VAF 37/280 reads (13%) | catalogued as COSV101005553, COSV101005613; called by muse, mutect2, varscan2
- SYT3 | c.1053T>A p.F351L | Missense Mutation (SNP) | VAF 158/379 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV100144295; called by muse, mutect2, varscan2
- TUFT1 | c.937A>G p.K313E | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1254978626, COSV100777138; called by muse, mutect2, varscan2
- USP28 | c.2579+1G>A p.X860_splice | Splice Site (SNP) | VAF 102/380 reads (27%) | catalogued as COSV99136505; called by muse, mutect2, varscan2
- WDCP | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 84/296 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.884); catalogued as COSV99722210; called by muse, mutect2, varscan2
- ZGRF1 | c.3004A>T p.T1002S | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.684); catalogued as COSV100481275; called by muse, mutect2, varscan2
- ZNF821 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 214/1439 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV100546872; called by muse, mutect2, varscan2
- LRIT3 | c.1376G>A p.S459N | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- ADGRE3 | c.1266C>T p.I422= | Silent (SNP) | VAF 30/202 reads (15%) | catalogued as rs772035400, COSV99506621; called by muse, mutect2, varscan2
- AHRR | c.1755G>A p.S585= | Silent (SNP) | VAF 61/189 reads (32%) | catalogued as rs778155575, COSV100327940, COSV57091269; called by muse, mutect2, varscan2
- CDH9 | c.1503A>G p.K501= | Silent (SNP) | VAF 186/391 reads (48%) | catalogued as COSV99151651; called by muse, mutect2, varscan2
- FAM126A | c.750T>C p.N250= | Silent (SNP) | VAF 52/698 reads (7%) | catalogued as COSV101327249; called by muse, mutect2
- JARID2 | c.1734C>T p.R578= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs764859787, COSV100522348; called by muse, varscan2
- MYO1F | c.1377C>T p.S459= | Silent (SNP) | VAF 24/141 reads (17%) | catalogued as rs780033132, COSV57802668; called by muse, mutect2, varscan2
- PGPEP1L | c.345C>T p.D115= | Silent (SNP) | VAF 86/556 reads (15%) | catalogued as rs1260764049, COSV99161560; called by muse, mutect2, varscan2
- PTPN5 | c.603C>T p.I201= | Silent (SNP) | VAF 55/325 reads (17%) | catalogued as rs367543231, COSV62125125, COSV62125631; ClinVar: not provided; called by muse, mutect2, varscan2
- TTBK1 | c.2931G>A p.A977= | Silent (SNP) | VAF 46/244 reads (19%) | catalogued as rs756556063, COSV52488106; called by muse, mutect2, varscan2
- WDR11 | c.1110A>T p.A370= | Silent (SNP) | VAF 172/487 reads (35%) | catalogued as COSV99676945; called by muse, mutect2, varscan2
- ZNF784 | c.60C>T p.S20= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100323271; called by muse, mutect2
- SNORD115-30 | n.6A>C | RNA (SNP) | VAF 136/858 reads (16%) | called by muse, mutect2, varscan2
